Somatic mutation profile of tumor specimen TCGA-EB-A42Y-01A (aliquot TCGA-EB-A42Y-01A-12D-A24R-08) from TCGA case TCGA-EB-A42Y, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 73.1 years (26,712 days).
Specimen TCGA-EB-A42Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa54f7af-571c-4c80-b930-6065121ff524.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A42Y-10A (Blood Derived Normal), aliquot TCGA-EB-A42Y-10A-01D-A24R-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33144604-9026-449e-a6fd-2450e7d0ef1e

The open-access MAF lists 67 somatic variants for this specimen: 55 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 7, Splice Site 3, Intron 2, RNA 2, Nonsense Mutation 1, 3'UTR 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 21/45 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: other / pathogenic / likely pathogenic; called by muse, varscan2
- KIT | c.1924A>G p.K642E | Missense Mutation (SNP) | VAF 62/123 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913512, CM002803, COSV55387507, COSV55411978; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADCY8 | c.3011G>A p.G1004E | Missense Mutation (SNP) | VAF 74/217 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV53905875; called by muse, mutect2, varscan2
- ALPI | c.518C>G p.A173G | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55014946; called by muse, mutect2, varscan2
- ARHGAP31 | c.4176G>T p.L1392F | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV51794102; called by muse, mutect2, varscan2
- ASAP3 | c.1624C>T p.R542C | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs781443284, COSV60875302; called by muse, mutect2, varscan2
- BCL11B | c.1168C>T p.R390W (on ENST00000357195 / NM_001282237.2; = p.R319W on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61736114; called by muse, mutect2, varscan2
- BLNK | c.700A>G p.T234A | Missense Mutation (SNP) | VAF 70/148 reads (47%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV56411698; called by muse, mutect2, varscan2
- BTAF1 | c.253+2T>A p.X85_splice | Splice Site (SNP) | VAF 18/36 reads (50%) | catalogued as COSV56435051; called by mutect2, varscan2
- C11orf42 | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV56410031; called by muse, mutect2, varscan2
- CASD1 | c.261T>A p.H87Q | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV51973044; called by muse, mutect2, varscan2
- CDH13 | c.515A>G p.K172R | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (1); PolyPhen possibly damaging (0.737); catalogued as rs749236696, COSV51827630; called by muse, mutect2, varscan2
- CDH9 | c.1420G>T p.V474F | Missense Mutation (SNP) | VAF 38/253 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV50299398; called by muse, mutect2, varscan2
- CELA2A | c.712G>A p.G238R | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs1261145180, COSV100657485, COSV62747647; called by muse, mutect2, varscan2
- CFAP47 | c.1555A>C p.I519L | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as COSV52885828; called by muse, mutect2, varscan2
- CYP1A1 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs776797048, COSV65697433; called by muse, mutect2, varscan2
- CYTH4 | c.174G>T p.M58I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV50633085; called by muse, mutect2, varscan2
- DKK3 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs768404301, COSV58868983; called by muse, mutect2, varscan2
- DPYD | c.2026G>A p.G676R | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1381816413, COSV64600105; called by muse, mutect2, varscan2
- DRD1 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs182894202; called by muse, mutect2, varscan2
- DSCAM | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 110/259 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as rs369222297, COSV68036796; called by muse, mutect2, varscan2
- DUOX2 | c.4314G>C p.E1438D | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV66532591; called by muse, mutect2, varscan2
- EXO1 | c.142A>G p.K48E | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV62217874; called by muse, mutect2
- FLNA | c.6716A>G p.H2239R (on ENST00000369850 / NM_001110556.2; = p.H2231R on NM_001456.3) | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.886); catalogued as COSV61044572; called by muse, mutect2, varscan2
- FN1 | c.6144A>T p.Q2048H | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); catalogued as COSV60554870; called by muse, mutect2, varscan2
- GRIN2B | c.3679A>C p.T1227P | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV74206244; called by muse, mutect2, varscan2
- HCK | c.893C>T p.S298L | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs747503111, COSV52941977; called by muse, mutect2, varscan2
- HCN1 | c.1896G>C p.M632I | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV57515561, COSV57538141; called by muse, mutect2, varscan2
- KL | c.2133G>T p.W711C | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752742169, COSV66308996; called by muse, mutect2, varscan2
- KRT71 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV57291047; called by muse, mutect2, varscan2
- LRRC3B | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV101185747, COSV67520069; called by muse, mutect2, varscan2
- MIGA1 | c.1783C>A p.R595S | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs376057702, COSV66223830; called by muse, mutect2, varscan2
- MYH2 | c.4966C>T p.L1656F | Missense Mutation (SNP) | VAF 71/140 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.667); catalogued as rs369083161, COSV55449034; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAA25 | c.783T>G p.D261E | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55704924; called by muse, mutect2, varscan2
- NFATC3 | c.1352G>T p.G451V | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60474673; called by muse, mutect2, varscan2
- OR52D1 | c.906G>T p.E302D | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV59487670; called by muse, mutect2, varscan2
- OR6M1 | c.13A>G p.S5G | Missense Mutation (SNP) | VAF 57/68 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV58433887; called by muse, mutect2, varscan2
- PGAP4 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs751875311, COSV66387805, COSV66388432; called by muse, mutect2, varscan2
- PTEN | c.791T>G p.M264R | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV64297978; called by muse, mutect2, varscan2
- PUM1 | c.2323+2T>G p.X775_splice | Splice Site (SNP) | VAF 114/235 reads (49%) | catalogued as COSV57086571; called by muse, mutect2, varscan2
- RECQL5 | c.902T>G p.V301G | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV58641698; called by muse, mutect2
- RP1 | c.787+2T>G p.X263_splice | Splice Site (SNP) | VAF 25/72 reads (35%) | catalogued as rs1489761807, COSV55118574; called by muse, mutect2, varscan2
- RXFP3 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV57506132; called by muse, mutect2, varscan2
- SLC15A2 | c.1692A>C p.E564D | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.03); catalogued as COSV55198285; called by muse, mutect2, varscan2
- SLC40A1 | c.100C>T p.L34F | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV53723280; called by muse, mutect2, varscan2
- SLC4A8 | c.2824A>C p.I942L | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV60653650; called by muse, mutect2, varscan2
- STIM2 | c.1279T>G p.L427V | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV52839970; called by muse, mutect2, varscan2
- SYNJ1 | c.2898A>C p.E966D | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV59149844; called by muse, mutect2, varscan2
- TMCO3 | c.1540G>C p.V514L | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV64807931; called by muse, mutect2, varscan2
- TTN | c.39506T>A p.V13169D (on ENST00000591111; = p.V5745D on NM_003319.4) | Missense Mutation (SNP) | VAF 63/161 reads (39%) | PolyPhen probably damaging (0.962); catalogued as COSV60114300; called by muse, mutect2, varscan2
- VPS13D | c.6028C>T p.Q2010* | Nonsense Mutation (SNP) | VAF 8/17 reads (47%) | catalogued as COSV50645146; called by muse, mutect2, varscan2
- WWTR1 | c.916C>T p.H306Y | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV62291571; called by muse, mutect2
- XIRP2 | c.9547G>A p.G3183R (on ENST00000628543; = p.G3358R on NM_152381.6) | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54706607; called by muse, mutect2, varscan2
- CBL | c.1107_1118del p.L370_E373del | In Frame Del (DEL) | VAF 51/57 reads (89%) | called by mutect2, pindel, varscan2
- SOX10 | c.1188_1198del p.R397* | Frame Shift Del (DEL) | VAF 13/51 reads (25%) | called by mutect2, pindel, varscan2
- ADGRD1 | c.1002G>A p.L334= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV55447535, COSV55453046; called by muse, mutect2, varscan2
- DOCK9 | c.538C>T p.L180= (on ENST00000376460 / NM_001366676.2; = p.L181= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as COSV59632273; called by muse, mutect2
- FMO4 | c.873C>T p.I291= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV63001287; called by muse, mutect2, varscan2
- FREM1 | c.3213C>T p.G1071= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV66524935; called by muse, mutect2, varscan2
- IFNA13 | c.12G>A p.S4= | Silent (SNP) | VAF 44/108 reads (41%) | catalogued as rs1361849379, COSV71924509; called by muse, mutect2, varscan2
- KCNA2 | c.879C>T p.L293= | Silent (SNP) | VAF 55/118 reads (47%) | catalogued as COSV60370255; called by muse, mutect2, varscan2
- TSHZ1 | c.2511C>T p.L837= (on ENST00000580243 / NM_001308210.2; = p.L792= on NM_005786.6) | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as rs1482865419, COSV59010973; called by muse, mutect2, varscan2
- AL163540.1 | n.45G>A | RNA (SNP) | VAF 62/161 reads (39%) | called by muse, mutect2, varscan2
- ECT2 | c.*2G>C | 3'UTR (SNP) | VAF 25/55 reads (45%) | catalogued as COSV99221579; called by muse, mutect2, varscan2
- SNORD115-42 | n.6G>A | RNA (SNP) | VAF 118/269 reads (44%) | catalogued as rs577950141; called by muse, mutect2, varscan2
- SSX5 | c.69+175A>C | Intron (SNP) | VAF 45/60 reads (75%) | catalogued as rs782397307, COSV61254692; called by muse, mutect2, varscan2
- TTN | c.10360+2334T>G | Intron (SNP) | VAF 35/84 reads (42%) | catalogued as COSV100621093; called by muse, mutect2, varscan2
